Somatic mutation profile of tumor specimen 0DUKHK from CCDI case PBCLKC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 1.8 years (649 days).
Specimen 0DUKHK: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7efd51d-cdd1-4af3-bb4a-daa1b7f8e12d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUKIW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9a066fa-594a-4e8d-a558-603008c149a0

The open-access MAF lists 17 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 6, Nonsense Mutation 2, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3521T>G p.F1174C | Missense Mutation (SNP) | VAF 79/384 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519697, COSV66558767, COSV66560921; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDI2 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 60/192 reads (31%) | catalogued as COSV60780702; called by muse, mutect2, varscan2
- PRRT4 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV71055032; called by muse, mutect2
- SASH3 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs771879917, COSV63555648; called by muse, mutect2, varscan2
- SMTN | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs866181605; called by muse, mutect2, varscan2
- EIF3A | c.2287C>T p.R763* | Nonsense Mutation (SNP) | VAF 36/358 reads (10%) | called by muse, mutect2, varscan2
- NOTCH2 | c.1813A>G p.S605G | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- RNF40 | c.1919A>T p.K640M | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ALPP | c.381C>A p.G127= | Silent (SNP) | VAF 68/359 reads (19%) | called by muse, mutect2, varscan2
- CHRNE | c.510G>A p.T170= | Silent (SNP) | VAF 21/272 reads (8%) | catalogued as rs749454549; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- FRMPD4 | c.3102T>G p.G1034= | Silent (SNP) | VAF 43/130 reads (33%) | called by muse, mutect2, varscan2
- KCNK1 | c.477C>T p.H159= | Silent (SNP) | VAF 46/249 reads (18%) | catalogued as rs143943031; called by muse, mutect2, varscan2
- LILRA5 | c.570C>A p.T190= | Silent (SNP) | VAF 27/179 reads (15%) | called by muse, mutect2, varscan2
- SENP7 | c.2127C>G p.A709= | Silent (SNP) | VAF 38/244 reads (16%) | catalogued as COSV58615764; called by muse, mutect2, varscan2
- EIF4G1 | c.537+27C>A | Intron (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- PDIA5 | c.911-86C>T | Intron (SNP) | VAF 5/20 reads (25%) | catalogued as rs1382462494; called by mutect2, varscan2
- PSKH1 | c.-9G>A | 5'UTR (SNP) | VAF 26/89 reads (29%) | catalogued as rs746311787, COSV99344855; called by muse, mutect2, varscan2
